Somatic mutation profile of tumor specimen TCGA-44-6144-01A (aliquot TCGA-44-6144-01A-11D-1753-08) from TCGA case TCGA-44-6144, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 58.3 years (21,283 days).
Specimen TCGA-44-6144-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4ebb7726-3c8b-404b-82c4-5763196d4a72.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-44-6144-10A (Blood Derived Normal), aliquot TCGA-44-6144-10A-01D-1753-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a4848ff9-93df-4ba5-afa9-7af2de058ebd

The open-access MAF lists 240 somatic variants for this specimen: 177 protein-altering or splice-affecting, 58 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 164, Silent 58, Nonsense Mutation 8, Frame Shift Del 4, RNA 3, 5'Flank 1, 3'Flank 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA3 | c.2883C>T p.G961= | Silent (SNP) | VAF 7/17 reads (41%) | catalogued as rs1298655924, COSV57052813; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- DCX | c.184G>A p.D62N | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs104894779, CM980521, COSV57568772; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FBN1 | c.1837+1G>T p.X613_splice | Splice Site (SNP) | VAF 10/61 reads (16%) | catalogued as rs397515762, CS042164, CS098573, COSV57315310; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.1010G>T p.R337L | Missense Mutation (SNP) | VAF 10/21 reads (48%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as rs121912664, CM012663, CM104660, COSV52665150, COSV52691988, COSV52828545; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCC12 | c.3061G>A p.A1021T | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.627); catalogued as COSV60913470; called by muse, mutect2, varscan2
- AC126283.2 | c.938C>T p.A313V | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.121); catalogued as COSV67098510; called by muse, mutect2
- ADAMTS3 | c.3140G>T p.C1047F | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54390142; called by muse, mutect2, varscan2
- ALG13 | c.2629A>G p.T877A | Missense Mutation (SNP) | VAF 73/139 reads (53%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV99321913; called by muse, mutect2, varscan2
- ANKRD44 | c.1144A>C p.N382H | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT tolerated (0.52); PolyPhen benign (0.022); catalogued as COSV56554145; called by muse, mutect2, varscan2
- APOBEC3D | c.121A>C p.I41L | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.024); catalogued as COSV99328864; called by muse, mutect2, varscan2
- ASB7 | c.628C>T p.R210C | Missense Mutation (SNP) | VAF 4/51 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV58403410; called by muse, mutect2
- ASPM | c.6784A>C p.M2262L | Missense Mutation (SNP) | VAF 14/214 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.041); catalogued as COSV54128909; called by muse, mutect2
- ASPRV1 | c.130G>T p.G44W | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.869); catalogued as COSV100208449; called by muse, mutect2, varscan2
- ATAD2 | c.392G>T p.R131L | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.048); catalogued as COSV54876942, COSV54880175; called by muse, mutect2, varscan2
- BACH2 | c.2152C>T p.Q718* | Nonsense Mutation (SNP) | VAF 6/37 reads (16%) | catalogued as COSV57590843, COSV57592076; called by muse, mutect2, varscan2
- BCLAF1 | c.443C>A p.S148Y | Missense Mutation (SNP) | VAF 23/179 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); catalogued as COSV62141813; called by muse, mutect2, varscan2
- BIRC6 | c.12877A>C p.T4293P | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV70198566; called by muse, mutect2, varscan2
- BMP4 | c.1110A>T p.K370N | Missense Mutation (SNP) | VAF 21/123 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.141); catalogued as COSV55415789; called by muse, mutect2, varscan2
- C7 | c.940A>G p.R314G | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.258); catalogued as rs1470335746, COSV57473735; called by muse, mutect2, varscan2
- CACNG7 | c.271G>T p.E91* | Nonsense Mutation (SNP) | VAF 12/37 reads (32%) | catalogued as COSV55814190, COSV55816006; called by muse, mutect2, varscan2
- CAPRIN2 | c.688G>T p.E230* | Nonsense Mutation (SNP) | VAF 63/249 reads (25%) | catalogued as COSV51832219; called by muse, mutect2, varscan2
- CCDC191 | c.407A>G p.K136R | Missense Mutation (SNP) | VAF 34/73 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as rs202171733, COSV55671764; called by muse, mutect2, varscan2
- CCDC85A | c.1581G>T p.W527C | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV68150124; called by muse, mutect2, varscan2
- CD19 | c.238A>T p.I80F | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as COSV61188434; called by muse, mutect2, varscan2
- CD300C | c.314C>A p.A105E | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.794); catalogued as COSV58170180; called by muse, mutect2
- CD300C | c.312C>A p.D104E | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58170189; called by muse, mutect2
- CELSR1 | c.4555C>T p.P1519S | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.386); catalogued as rs775503253, COSV53088779; called by muse, mutect2
- CEP112 | c.693G>T p.M231I | Missense Mutation (SNP) | VAF 27/112 reads (24%) | SIFT tolerated (0.34); PolyPhen benign (0.022); catalogued as COSV67138725; called by muse, mutect2, varscan2
- CFAP46 | c.7379A>T p.H2460L | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.029); catalogued as COSV99584386; called by muse, mutect2, varscan2
- CHD7 | c.3014C>G p.T1005R | Missense Mutation (SNP) | VAF 50/156 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV71109709; called by muse, mutect2, varscan2
- CLEC2D | c.320A>G p.D107G | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV99324938; called by muse, mutect2, varscan2
- CLPTM1 | c.317A>T p.H106L | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV61611733; called by muse, mutect2, varscan2
- CNKSR2 | c.957+1del | Frame Shift Del (DEL) | VAF 20/43 reads (47%) | catalogued as COSV54262359; called by mutect2, varscan2
- COL12A1 | c.8368C>A p.P2790T | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.971); catalogued as COSV59394835; called by muse, mutect2, varscan2
- COPS7A | c.64G>A p.A22T | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT tolerated (0.32); PolyPhen benign (0.172); catalogued as COSV99976419; called by muse, mutect2, varscan2
- CPS1 | c.794C>A p.P265Q | Missense Mutation (SNP) | VAF 103/332 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM125128, COSV51802903, COSV51808697; called by muse, mutect2, varscan2
- CRB1 | c.2001G>T p.K667N | Missense Mutation (SNP) | VAF 18/166 reads (11%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.725); catalogued as COSV66329830; called by muse, mutect2, varscan2
- CRISP1 | c.610G>A p.D204N | Missense Mutation (SNP) | VAF 36/164 reads (22%) | SIFT tolerated (0.57); PolyPhen benign (0.178); catalogued as COSV59993442; called by muse, mutect2, varscan2
- CSMD3 | c.3832G>T p.G1278* (on ENST00000297405 / NM_001363185.1; = p.G1174* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 15/153 reads (10%) | catalogued as COSV52165357, COSV99847243; called by muse, mutect2, varscan2
- CUBN | c.10763G>C p.G3588A | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV64714569; called by muse, varscan2
- CWH43 | c.1267G>T p.A423S | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV56938402, COSV56943356; called by muse, mutect2, varscan2
- DAB2IP | c.3325G>T p.V1109L (on ENST00000408936; = p.V1081L on NM_032552.3) | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs200849707, COSV52258371; called by muse, mutect2, varscan2
- DCAF13 | c.296G>T p.R99L | Missense Mutation (SNP) | VAF 20/176 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.142); catalogued as COSV52570722, COSV52571587; called by muse, mutect2, varscan2
- DCST1 | c.304T>G p.C102G | Missense Mutation (SNP) | VAF 20/113 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99792946; called by muse, mutect2, varscan2
- DDI1 | c.994C>A p.L332I | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56376415; called by muse, mutect2, varscan2
- DEFA4 | c.209T>A p.V70E | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.31); catalogued as COSV52404655; called by muse, mutect2, varscan2
- DENND1A | c.2899C>A p.P967T | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.003); catalogued as COSV65349742; called by muse, mutect2
- DGKB | c.2210G>T p.G737V | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV51778972; called by muse, mutect2, varscan2
- DLG2 | c.2008G>T p.E670* | Nonsense Mutation (SNP) | VAF 11/77 reads (14%) | catalogued as COSV54639748; called by muse, mutect2, varscan2
- DLL1 | c.377C>A p.A126D | Missense Mutation (SNP) | VAF 34/141 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV64537340; called by muse, mutect2, varscan2
- DNAH11 | c.6194G>T p.W2065L | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV60953604; called by muse, mutect2, varscan2
- DNAH9 | c.11407G>T p.V3803L | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV52347108, COSV52358223; called by muse, mutect2, varscan2
- E2F7 | c.2296G>T p.G766C | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.62); catalogued as COSV59739368; called by muse, mutect2, varscan2
- E2F7 | c.1245G>T p.Q415H | Missense Mutation (SNP) | VAF 43/124 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as COSV59739380; called by muse, mutect2, varscan2
- EIF3H | c.418T>A p.Y140N | Missense Mutation (SNP) | VAF 15/183 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV52666316; called by muse, mutect2
- EPHA7 | c.1136G>C p.C379S | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.288); catalogued as COSV65181925, COSV65183626; called by muse, mutect2, varscan2
- EPS15L1 | c.1643C>T p.S548F | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.898); catalogued as rs770275949, COSV50168401; called by muse, mutect2, varscan2
- EPSTI1 | c.547A>G p.R183G | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.78); catalogued as COSV58045186; called by muse, mutect2, varscan2
- FAM135B | c.1076T>C p.L359P | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV52709678, COSV52718533; called by muse, mutect2, varscan2
- FAM184A | c.2189C>T p.T730M | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.944); catalogued as rs773464428, COSV58851698; called by muse, mutect2, varscan2
- FAM71D | c.1134C>A p.S378R | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.462); catalogued as COSV61295351; called by muse, mutect2, varscan2
- FAT4 | c.10660G>T p.G3554C | Missense Mutation (SNP) | VAF 39/135 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs777099226, COSV58682113; called by muse, mutect2, varscan2
- FBN1 | c.8401G>A p.D2801N | Missense Mutation (SNP) | VAF 26/159 reads (16%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs868087455, COSV57315304; called by muse, mutect2, varscan2
- FCRL4 | c.934G>A p.V312M | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.796); catalogued as rs142198646; called by muse, mutect2, varscan2
- FOXP2 | c.2080A>T p.N694Y | Missense Mutation (SNP) | VAF 37/124 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1251042963, COSV63485253; called by muse, mutect2, varscan2
- GDF15 | c.25del p.V9* | Frame Shift Del (DEL) | VAF 4/34 reads (12%) | catalogued as COSV53250680; called by mutect2, pindel, varscan2
- GJA9 | c.1316_1329del p.P439Qfs*23 | Frame Shift Del (DEL) | VAF 57/131 reads (44%) | catalogued as rs747738934; called by mutect2, pindel, varscan2
- GMDS | c.442G>T p.V148L | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.054); catalogued as COSV66433293; called by muse, mutect2, varscan2
- GPNMB | c.522C>G p.I174M | Missense Mutation (SNP) | VAF 43/131 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.049); catalogued as rs746852051, COSV51698103; called by muse, mutect2, varscan2
- GPRASP2 | c.196G>T p.A66S | Missense Mutation (SNP) | VAF 35/61 reads (57%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59991054; called by muse, mutect2, varscan2
- GRM6 | c.1718C>A p.P573H | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.03); catalogued as COSV51440060, COSV99179948; called by muse, mutect2, varscan2
- GTSE1 | c.1324C>G p.Q442E | Missense Mutation (SNP) | VAF 32/140 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.347); catalogued as COSV71889180; called by muse, mutect2, varscan2
- HCK | c.460G>T p.A154S | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.9); catalogued as rs866857595, COSV99393924; called by muse, mutect2, varscan2
- HCRTR2 | c.885G>C p.Q295H | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV63795443; called by muse, mutect2, varscan2
- HECTD1 | c.1531A>G p.K511E | Missense Mutation (SNP) | VAF 72/276 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.344); catalogued as COSV67946070; called by muse, varscan2
- HECTD1 | c.1490A>G p.K497R | Missense Mutation (SNP) | VAF 62/263 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.019); catalogued as COSV67946073; called by muse, varscan2
- HK2 | c.413T>C p.M138T | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.917); catalogued as COSV51874989; called by muse, mutect2, varscan2
- HK3 | c.1382G>T p.G461V | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV52839477; called by muse, mutect2, varscan2
- HOXA5 | c.448G>A p.E150K | Missense Mutation (SNP) | VAF 38/86 reads (44%) | SIFT tolerated (0.19); PolyPhen benign (0.369); catalogued as rs764896847, COSV56072957; called by muse, mutect2, varscan2
- HS3ST4 | c.1311G>T p.L437F | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0.062); catalogued as COSV100500783; called by muse, mutect2, varscan2
- IL21R | c.1099A>T p.R367W | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as COSV61970017; called by muse, mutect2, varscan2
- IQUB | c.677C>A p.T226N | Missense Mutation (SNP) | VAF 62/211 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.554); catalogued as COSV61238832; called by muse, mutect2, varscan2
- KCNJ2 | c.640G>T p.V214L | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.355); catalogued as COSV54661437; called by muse, mutect2, varscan2
- KIR2DL3 | c.89C>A p.S30Y | Missense Mutation (SNP) | VAF 9/182 reads (5%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.906); catalogued as rs770710004, COSV60899397; called by muse, mutect2
- KRTAP10-6 | c.196C>A p.P66T | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.249); catalogued as rs782142878, COSV100552673; called by muse, mutect2, varscan2
- LAMB1 | c.1273C>G p.Q425E | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV55963979; called by muse, mutect2, varscan2
- LDHB | c.103G>T p.A35S | Missense Mutation (SNP) | VAF 26/121 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.758); catalogued as COSV63364622; called by muse, mutect2, varscan2
- LEO1 | c.1249G>C p.E417Q | Missense Mutation (SNP) | VAF 27/125 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.631); catalogued as COSV55175613; called by muse, mutect2, varscan2
- LRRTM4 | c.1096G>C p.V366L | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as COSV69139878; called by muse, mutect2, varscan2
- MAP2 | c.113G>T p.G38V | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV52289166; called by muse, mutect2, varscan2
- MARK4 | c.541G>A p.D181N | Missense Mutation (SNP) | VAF 9/102 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53463409; called by muse, mutect2
- MEFV | c.706G>A p.G236R | Missense Mutation (SNP) | VAF 29/101 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.177); catalogued as COSV54821211; called by muse, mutect2, varscan2
- MLEC | c.233G>T p.R78L | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV57329517, COSV57329789; called by muse, mutect2
- MRPS23 | c.544G>T p.D182Y | Missense Mutation (SNP) | VAF 32/110 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.275); catalogued as COSV58032178; called by muse, mutect2, varscan2
- MTERF4 | c.226T>G p.C76G | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV99612452; called by muse, mutect2, varscan2
- MUC16 | c.41704C>T p.L13902F | Missense Mutation (SNP) | VAF 38/122 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.991); catalogued as rs750961581, COSV66691560; called by muse, mutect2, varscan2
- MUC3A | c.400T>A p.F134I | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious, low confidence (0.01); catalogued as COSV100114330; called by muse, mutect2, varscan2
- MYO1G | c.670A>C p.N224H | Missense Mutation (SNP) | VAF 36/143 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as COSV51854406; called by muse, mutect2, varscan2
- NCOR2 | c.7079T>C p.L2360P | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); catalogued as COSV100657117; called by muse, varscan2
- NECTIN4 | c.1288A>T p.N430Y | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.737); catalogued as COSV63512520; called by muse, mutect2, varscan2
- NEK3 | c.298C>A p.P100T | Missense Mutation (SNP) | VAF 29/106 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.038); catalogued as COSV51616735; called by muse, varscan2
- NES | c.955G>T p.G319C | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.667); catalogued as COSV100957820; called by muse, mutect2, varscan2
- NGEF | c.1876C>G p.Q626E | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.68); catalogued as COSV50919981, COSV50929099; called by muse, mutect2, varscan2
- NPAP1 | c.3376C>A p.H1126N | Missense Mutation (SNP) | VAF 36/130 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV61506407; called by muse, mutect2, varscan2
- NTN1 | c.1396G>T p.V466L | Missense Mutation (SNP) | VAF 35/115 reads (30%) | SIFT tolerated (0.4); PolyPhen benign (0.005); catalogued as COSV51481253; called by muse, mutect2, varscan2
- OBSCN | c.3638G>C p.R1213P | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.625); catalogued as COSV52769361; called by muse, mutect2, varscan2
- OR10G8 | c.541C>T p.P181S | Missense Mutation (SNP) | VAF 26/139 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV70908467; called by muse, mutect2, varscan2
- OR5A2 | c.116C>G p.T39R | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs373273792, COSV57390897, COSV57391147; called by muse, mutect2, varscan2
- OR5L2 | c.623G>A p.S208N | Missense Mutation (SNP) | VAF 29/157 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.288); catalogued as COSV65723864; called by muse, mutect2, varscan2
- OR8I2 | c.94C>A p.L32I | Missense Mutation (SNP) | VAF 42/226 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV56167645, COSV56170785; called by muse, varscan2
- OR8I2 | c.266G>T p.R89L | Missense Mutation (SNP) | VAF 26/216 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV100135978; called by muse, varscan2
- OR8J3 | c.740C>T p.A247V | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT tolerated (0.95); PolyPhen benign (0.118); catalogued as COSV56880409; called by muse, mutect2, varscan2
- OTUD7B | c.612G>T p.W204C | Missense Mutation (SNP) | VAF 26/104 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64916029; called by muse, mutect2, varscan2
- PCLO | c.12486G>T p.E4162D | Missense Mutation (SNP) | VAF 25/117 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.361); catalogued as COSV61631684; called by muse, mutect2, varscan2
- PDE8B | c.2182G>C p.E728Q | Missense Mutation (SNP) | VAF 38/93 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53736862; called by muse, mutect2, varscan2
- PHF21B | c.1565C>G p.P522R | Missense Mutation (SNP) | VAF 20/154 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.01); catalogued as COSV57557937; called by muse, mutect2, varscan2
- PLXNB1 | c.1763G>C p.C588S | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56489158; called by muse, mutect2, varscan2
- PNPLA1 | c.874C>A p.R292S (on ENST00000394571 / NM_001374623.1; = p.R197S on NM_173676.2) | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV100462918; called by muse, mutect2
- POLD2 | c.1196C>A p.P399Q | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV99788616; called by muse, mutect2, varscan2
- PPFIBP1 | c.2254T>G p.Y752D (on ENST00000318304 / NM_177444.3; = p.Y746D on NM_003622.4) | Missense Mutation (SNP) | VAF 23/107 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57290687; called by muse, mutect2, varscan2
- PRG4 | c.1564C>A p.P522T | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.047); catalogued as rs752899027, COSV63355422, COSV63355712; called by muse, varscan2
- PRMT8 | c.1046G>A p.R349Q | Missense Mutation (SNP) | VAF 31/112 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as rs745561387, COSV54212632; called by muse, mutect2, varscan2
- RCOR3 | c.1451T>A p.I484N | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.601); catalogued as COSV65364999, COSV65365542; called by muse, mutect2, varscan2
- RFX1 | c.977C>T p.T326M | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs775693470, COSV54329537; called by muse, mutect2, varscan2
- RNF17 | c.449A>G p.E150G | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.023); catalogued as COSV55039190; called by muse, mutect2, varscan2
- RNF213 | c.1853G>A p.S618N | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.061); catalogued as COSV60622804; called by muse, mutect2, varscan2
- ROBO2 | c.2984C>A p.T995N | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.814); catalogued as COSV59908747; called by muse, mutect2, varscan2
- RYR2 | c.5467A>T p.K1823* | Nonsense Mutation (SNP) | VAF 35/248 reads (14%) | catalogued as COSV63682216; called by muse, mutect2, varscan2
- S1PR3 | c.533G>A p.C178Y | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63980506; called by muse, mutect2, varscan2
- SAMD10 | c.562C>T p.R188W | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV53880077; called by muse, mutect2, varscan2
- SCFD1 | c.1410G>T p.E470D | Missense Mutation (SNP) | VAF 34/153 reads (22%) | SIFT tolerated (0.85); PolyPhen benign (0.022); catalogued as COSV61723686; called by muse, mutect2, varscan2
- SCN3A | c.4149C>G p.D1383E | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT tolerated (0.7); PolyPhen benign (0.062); catalogued as COSV51808468; called by muse, mutect2, varscan2
- SETBP1 | c.2104G>T p.A702S | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.34); PolyPhen benign (0.359); catalogued as COSV56320353; called by muse, mutect2, varscan2
- SEZ6L2 | c.833G>A p.G278D (on ENST00000308713 / NM_001114099.3; = p.G208D on NM_012410.4) | Missense Mutation (SNP) | VAF 17/111 reads (15%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.726); catalogued as COSV58099107; called by muse, mutect2, varscan2
- SLC13A1 | c.1105G>A p.V369I | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.79); PolyPhen benign (0.005); catalogued as COSV52010686; called by muse, mutect2, varscan2
- SLC5A12 | c.227G>T p.R76L | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.451); catalogued as COSV54820885; called by muse, mutect2, varscan2
- SLC6A5 | c.861C>A p.Y287* | Nonsense Mutation (SNP) | VAF 71/252 reads (28%) | catalogued as COSV54225932; called by muse, mutect2, varscan2
- SMG5 | c.1075G>C p.V359L | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.069); catalogued as COSV62435029; called by muse, mutect2, varscan2
- SPINK14 | c.55G>T p.V19L | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.031); catalogued as COSV100810972; called by muse, mutect2, varscan2
- STAT1 | c.460A>T p.M154L | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV100738757, COSV63115890; called by muse, mutect2, varscan2
- STK11 | c.322A>T p.K108* | Nonsense Mutation (SNP) | VAF 57/132 reads (43%) | catalogued as COSV58822999; called by muse, mutect2, varscan2
- SYNE1 | c.6234G>C p.Q2078H (on ENST00000367255 / NM_182961.4; = p.Q2085H on NM_033071.3) | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.051); catalogued as COSV54967249; called by muse, mutect2, varscan2
- TAS2R38 | c.499C>A p.H167N | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT tolerated (0.29); PolyPhen benign (0.062); catalogued as COSV71885352; called by muse, mutect2, varscan2
- TCEAL5 | c.466C>G p.Q156E | Missense Mutation (SNP) | VAF 61/102 reads (60%) | SIFT tolerated (0.75); PolyPhen benign (0.163); catalogued as COSV101013113; called by muse, mutect2, varscan2
- TCF21 | c.64G>A p.G22R | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.055); catalogued as rs768488824, COSV99399520; called by muse, mutect2, varscan2
- TEKT4 | c.1052G>C p.R351P | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54624529, COSV54625971; called by muse, mutect2, varscan2
- TH | c.1522C>A p.R508S (on ENST00000381178 / NM_199292.3; = p.R477S on NM_000360.4) | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.83); PolyPhen benign (0.035); catalogued as COSV51746994; called by muse, mutect2, varscan2
- TLR2 | c.2315A>T p.E772V | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.102); catalogued as COSV99472221; called by muse, mutect2, varscan2
- TPX2 | c.343G>A p.A115T | Missense Mutation (SNP) | VAF 36/136 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as COSV55919155; called by muse, mutect2, varscan2
- TRIM26 | c.1349G>C p.G450A | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV70982878; called by muse, mutect2, varscan2
- TRMT10A | c.420G>T p.Q140H | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.374); catalogued as COSV56744891; called by muse, varscan2
- TRPC4 | c.1107C>G p.H369Q | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.944); catalogued as COSV58998567; called by muse, mutect2, varscan2
- TRPM8 | c.2090T>A p.L697Q | Missense Mutation (SNP) | VAF 56/187 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.4); catalogued as COSV61221849; called by muse, mutect2, varscan2
- TRRAP | c.8279T>C p.M2760T (on ENST00000359863 / NM_001244580.1; = p.M2742T on NM_003496.3) | Missense Mutation (SNP) | VAF 30/106 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.276); catalogued as rs769247212, COSV62843393; called by muse, mutect2, varscan2
- TTC24 | c.1580C>T p.P527L | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.006); catalogued as COSV63997638; called by muse, mutect2, varscan2
- TTN | c.100549C>A p.P33517T (on ENST00000591111; = p.P26093T on NM_003319.4) | Missense Mutation (SNP) | VAF 37/194 reads (19%) | PolyPhen probably damaging (0.998); catalogued as rs758006957, COSV60016770; called by muse, mutect2, varscan2
- TUBGCP6 | c.2242C>A p.L748M | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.874); catalogued as COSV50542804; called by muse, mutect2
- TYR | c.7C>A p.L3M | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.824); catalogued as COSV99633735; called by muse, mutect2
- UBE3A | c.1523C>T p.T508I | Missense Mutation (SNP) | VAF 17/116 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.325); catalogued as COSV51664407; called by muse, mutect2, varscan2
- UBR2 | c.2272A>G p.I758V | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.922); catalogued as COSV65749685; called by muse, mutect2, varscan2
- UBXN11 | c.97G>A p.D33N | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0.006); catalogued as COSV59025583; called by muse, mutect2
- UPP2 | c.309G>A p.M103I | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.16); catalogued as COSV50046780; called by muse, mutect2, varscan2
- VAV3 | c.1865G>T p.G622V | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100579472; called by muse, mutect2, varscan2
- VCAM1 | c.1210C>A p.P404T | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); catalogued as COSV54119082; called by mutect2, varscan2
- VSTM4 | c.577C>G p.L193V | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as rs746608207, COSV60526006; called by muse, mutect2, varscan2
- WDHD1 | c.1455G>T p.L485F | Missense Mutation (SNP) | VAF 39/145 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV62213602; called by muse, mutect2, varscan2
- WDR90 | c.369G>T p.E123D | Missense Mutation (SNP) | VAF 81/223 reads (36%) | SIFT tolerated (0.23); PolyPhen benign (0.369); catalogued as COSV53469133; called by muse, mutect2, varscan2
- WSCD2 | c.577G>C p.A193P | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.097); catalogued as COSV54581937; called by muse, mutect2
- ZIM3 | c.886C>A p.Q296K | Missense Mutation (SNP) | VAF 24/175 reads (14%) | SIFT tolerated (0.91); PolyPhen benign (0.089); catalogued as COSV54142207; called by muse, mutect2, varscan2
- ZNF468 | c.72C>G p.C24W | Missense Mutation (SNP) | VAF 52/191 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.424); catalogued as COSV54694493; called by muse, mutect2, varscan2
- ZNF622 | c.1368G>T p.M456I | Missense Mutation (SNP) | VAF 34/104 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as COSV58073949; called by muse, mutect2, varscan2
- ZNF676 | c.1543G>A p.G515S (on ENST00000650058; = p.G483S on NM_001001411.3) | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); catalogued as COSV68092934; called by muse, mutect2, varscan2
- ZNF681 | c.1220C>T p.S407L | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.43); catalogued as COSV101267437, COSV68075592; called by muse, mutect2, varscan2
- ZNF773 | c.902G>T p.R301M | Missense Mutation (SNP) | VAF 41/131 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99989180; called by muse, mutect2, varscan2
- ZNF773 | c.903G>T p.R301S | Missense Mutation (SNP) | VAF 42/135 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as rs200220630, COSV99989182; called by muse, mutect2, varscan2
- ZP4 | c.154C>A p.P52T | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.38); PolyPhen benign (0.024); catalogued as COSV63911784; called by muse, mutect2, varscan2
- IGF2R | c.1573del p.E525Kfs*32 | Frame Shift Del (DEL) | VAF 17/112 reads (15%) | called by mutect2, pindel, varscan2
- KRTAP10-4 | c.196C>A p.P66T | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ANKRD23 | c.414T>C p.N138= | Silent (SNP) | VAF 25/107 reads (23%) | catalogued as COSV58412546; called by muse, mutect2, varscan2
- ATP12A | c.786A>C p.T262= | Silent (SNP) | VAF 36/225 reads (16%) | catalogued as rs753000528, COSV54515360; called by muse, mutect2, varscan2
- BDKRB1 | c.448C>A p.R150= | Silent (SNP) | VAF 13/55 reads (24%) | catalogued as COSV53706021; called by muse, mutect2, varscan2
- CASQ1 | c.438T>C p.A146= | Silent (SNP) | VAF 16/81 reads (20%) | catalogued as COSV63624104; called by muse, mutect2, varscan2
- CEL | c.2169C>A p.S723= (on ENST00000673714; = p.S720= on NM_001807.6) | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as COSV60827086; called by muse, mutect2
- COL14A1 | c.885A>G p.K295= | Silent (SNP) | VAF 3/47 reads (6%) | catalogued as COSV52853147, COSV99917853; called by muse, mutect2
- CSMD1 | c.7353G>A p.A2451= (on ENST00000520002; = p.A2450= on NM_033225.6) | Silent (SNP) | VAF 8/56 reads (14%) | catalogued as rs189926727; called by muse, mutect2, varscan2
- DCST1 | c.303C>A p.R101= | Silent (SNP) | VAF 20/112 reads (18%) | catalogued as COSV99792936; called by muse, mutect2, varscan2
- DDX43 | c.1164G>A p.K388= | Silent (SNP) | VAF 15/75 reads (20%) | catalogued as COSV64836818; called by muse, mutect2, varscan2
- DENND5A | c.240A>T p.R80= | Silent (SNP) | VAF 45/198 reads (23%) | catalogued as COSV60233203; called by muse, mutect2, varscan2
- DOCK7 | c.42G>T p.T14= | Silent (SNP) | VAF 33/132 reads (25%) | catalogued as COSV52003583; called by muse, mutect2, varscan2
- EGLN1 | c.924G>T p.T308= | Silent (SNP) | VAF 32/90 reads (36%) | catalogued as COSV100791245; called by muse, mutect2, varscan2
- FAM71B | c.858G>A p.G286= | Silent (SNP) | VAF 43/93 reads (46%) | catalogued as COSV57228358; called by muse, mutect2, varscan2
- FBXO15 | c.405G>A p.E135= | Silent (SNP) | VAF 17/46 reads (37%) | catalogued as COSV99503201; called by muse, mutect2, varscan2
- FCRL2 | c.903C>T p.V301= | Silent (SNP) | VAF 8/53 reads (15%) | catalogued as COSV63833414; called by muse, mutect2, varscan2
- FPR2 | c.972C>A p.A324= | Silent (SNP) | VAF 5/48 reads (10%) | catalogued as COSV60672675; called by muse, mutect2, varscan2
- GLG1 | c.1338G>T p.G446= | Silent (SNP) | VAF 11/90 reads (12%) | catalogued as COSV52666398; called by muse, mutect2, varscan2
- IBTK | c.45G>T p.L15= | Silent (SNP) | VAF 32/132 reads (24%) | catalogued as COSV60392571; called by muse, mutect2, varscan2
- IL26 | c.489T>A p.I163= | Silent (SNP) | VAF 16/85 reads (19%) | catalogued as COSV57488850; called by muse, mutect2, varscan2
- IPO9 | c.2340G>A p.E780= | Silent (SNP) | VAF 27/75 reads (36%) | catalogued as rs1239438792, COSV100843349, COSV64233529; called by muse, mutect2, varscan2
- ITPKC | c.1242T>G p.L414= | Silent (SNP) | VAF 14/163 reads (9%) | catalogued as COSV54574428; called by muse, mutect2
- KCNMA1 | c.1503G>A p.E501= | Silent (SNP) | VAF 14/43 reads (33%) | catalogued as COSV54281119, COSV99696227; called by muse, mutect2, varscan2
- KDM2A | c.1851A>T p.S617= | Silent (SNP) | VAF 16/69 reads (23%) | catalogued as COSV58189439; called by muse, mutect2, varscan2
- KDM3B | c.4110G>T p.V1370= | Silent (SNP) | VAF 35/92 reads (38%) | catalogued as COSV58690103; called by muse, mutect2, varscan2
- KLHL1 | c.465T>C p.S155= | Silent (SNP) | VAF 34/125 reads (27%) | catalogued as COSV64771477; called by muse, mutect2, varscan2
- LAMC3 | c.2412C>A p.P804= | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as COSV63090652; called by muse, mutect2, varscan2
- MCOLN1 | c.96T>C p.P32= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as rs779878653; called by mutect2, varscan2
- MERTK | c.2571C>G p.L857= | Silent (SNP) | VAF 26/83 reads (31%) | catalogued as rs762547386, COSV54928240; called by muse, mutect2, varscan2
- MGAT5 | c.519C>T p.Y173= | Silent (SNP) | VAF 55/249 reads (22%) | catalogued as rs149877815; called by muse, mutect2, varscan2
- MMP20 | c.519T>C p.N173= | Silent (SNP) | VAF 21/66 reads (32%) | catalogued as COSV52775231; called by muse, mutect2, varscan2
- MYPN | c.2817G>T p.T939= | Silent (SNP) | VAF 17/56 reads (30%) | catalogued as COSV62733436, COSV62734549; called by muse, mutect2, varscan2
- NAF1 | c.48C>T p.F16= | Silent (SNP) | VAF 4/19 reads (21%) | catalogued as rs1363583687, COSV56804183, COSV56805722; called by muse, mutect2, varscan2
- NCOR2 | c.7080C>T p.L2360= | Silent (SNP) | VAF 12/43 reads (28%) | catalogued as rs778552469, COSV100657115; called by muse, mutect2, varscan2
- NFIA | c.222A>T p.R74= | Silent (SNP) | VAF 17/82 reads (21%) | catalogued as COSV64536832; called by muse, mutect2, varscan2
- NOS1 | c.1653C>T p.I551= | Silent (SNP) | VAF 27/91 reads (30%) | catalogued as COSV57611365, COSV57616518; called by muse, mutect2, varscan2
- NXF3 | c.1188T>C p.D396= | Silent (SNP) | VAF 50/96 reads (52%) | catalogued as rs770379495, COSV67703358, COSV67704644; called by muse, mutect2, varscan2
- OBSCN | c.1389G>T p.G463= | Silent (SNP) | VAF 7/73 reads (10%) | catalogued as rs1056844476, COSV52769340; called by muse, mutect2
- OR1A2 | c.697C>T p.L233= | Silent (SNP) | VAF 55/142 reads (39%) | catalogued as rs746394716, COSV101126345; called by muse, mutect2, varscan2
- OR5L1 | c.810T>A p.A270= | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as COSV61733657; called by muse, mutect2, varscan2
- OSBPL5 | c.1869G>A p.P623= | Silent (SNP) | VAF 15/61 reads (25%) | catalogued as rs202021793, COSV55141330, COSV99720166; called by muse, mutect2, varscan2
- PACSIN3 | c.99C>T p.H33= | Silent (SNP) | VAF 36/85 reads (42%) | catalogued as rs1323861492, COSV54065886; called by muse, mutect2, varscan2
- PDE1C | c.819C>T p.T273= | Silent (SNP) | VAF 23/98 reads (23%) | catalogued as rs758775742, COSV58512212; called by muse, mutect2, varscan2
- PPIP5K2 | c.1881T>A p.L627= | Silent (SNP) | VAF 38/103 reads (37%) | catalogued as COSV58605196; called by muse, mutect2, varscan2
- PRKCB | c.477C>T p.R159= | Silent (SNP) | VAF 14/43 reads (33%) | catalogued as rs573327064, COSV57777260; called by muse, mutect2, varscan2
- PWWP3B | c.510A>G p.Q170= | Silent (SNP) | VAF 9/15 reads (60%) | catalogued as rs1412846647, COSV100531095; called by muse, mutect2, varscan2
- RAPGEF6 | c.2370C>T p.S790= | Silent (SNP) | VAF 26/64 reads (41%) | catalogued as rs752429008, COSV99725998; called by muse, mutect2, varscan2
- RPTN | c.688C>A p.R230= | Silent (SNP) | VAF 43/238 reads (18%) | catalogued as COSV60167108; called by muse, mutect2, varscan2
- SCN1A | c.2328C>A p.I776= (on ENST00000303395 / NM_001202435.3; = p.I765= on NM_006920.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 23/113 reads (20%) | catalogued as COSV57668439; called by muse, mutect2, varscan2
- SIPA1L2 | c.330C>T p.I110= | Silent (SNP) | VAF 31/196 reads (16%) | catalogued as COSV53389446; called by muse, mutect2, varscan2
- SLITRK6 | c.714A>G p.P238= | Silent (SNP) | VAF 20/113 reads (18%) | catalogued as rs766684857, COSV68390035; called by muse, mutect2, varscan2
- SYNE1 | c.1569G>T p.L523= (on ENST00000367255 / NM_182961.4; = p.L530= on NM_033071.3) | Silent (SNP) | VAF 35/140 reads (25%) | catalogued as COSV54967295, COSV55010874; called by muse, mutect2, varscan2
- SYNGR4 | c.102C>T p.S34= | Silent (SNP) | VAF 8/58 reads (14%) | catalogued as COSV61225291; called by muse, mutect2, varscan2
- SYT6 | c.393C>A p.A131= (on ENST00000610222 / NM_001366225.1; = p.A46= on NM_205848.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 10/68 reads (15%) | catalogued as COSV65773571; called by muse, mutect2, varscan2
- VAT1L | c.942G>C p.A314= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as COSV56816891, COSV56818718; called by muse, mutect2, varscan2
- XIRP1 | c.1836A>T p.S612= | Silent (SNP) | VAF 19/49 reads (39%) | catalogued as COSV61138195; called by muse, mutect2, varscan2
- ZNF107 | c.1917A>T p.A639= | Silent (SNP) | VAF 17/52 reads (33%) | catalogued as COSV61328296; called by muse, mutect2, varscan2
- ZSWIM8 | c.2169A>T p.G723= | Silent (SNP) | VAF 21/57 reads (37%) | catalogued as COSV67132313; called by muse, mutect2, varscan2
- AC244258.1 | n.919G>C | RNA (SNP) | VAF 47/171 reads (27%) | catalogued as rs747082410; called by muse, mutect2, varscan2
- AL136439.1 | chr13:27665841 A>T | 3'Flank (SNP) | VAF 13/46 reads (28%) | catalogued as COSV101294865; called by muse, mutect2, varscan2
- SNORD116-7 | n.21A>T | RNA (SNP) | VAF 41/121 reads (34%) | called by muse, mutect2, varscan2
- TTI2 | chr8:33513508 T>C | 5'Flank (SNP) | VAF 30/93 reads (32%) | catalogued as rs374176334; called by muse, mutect2
- UBTFL2 | n.692G>T | RNA (SNP) | VAF 11/110 reads (10%) | called by muse, mutect2, varscan2
